Somatic mutation profile of tumor specimen MMRF_1802_1_BM_CD138pos (aliquot MMRF_1802_1_BM_CD138pos_T1_KBS5U_L05076) from MMRF case MMRF_1802, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 63.8 years (23,301 days).
Specimen MMRF_1802_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bb797571-8873-4eab-860f-27a6a0385545.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1802_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1802_1_PB_Whole_C2_KBS5U_L05084; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a7581929-eba8-4dc0-9cba-1843ca489a04

The open-access MAF lists 78 somatic variants for this specimen: 30 protein-altering or splice-affecting, 8 silent, 40 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, 3'UTR 27, Intron 9, Silent 8, 5'UTR 2, 3'Flank 2, Splice Region 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 44/91 reads (48%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS2 | c.1373G>A p.R458H | Missense Mutation (SNP) | VAF 21/64 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs768230986, COSV99201251; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- C17orf97 | c.26C>T p.A9V | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.828); catalogued as rs560339445; called by muse, mutect2
- COL23A1 | c.732C>T p.G244= | Splice Region (SNP) | VAF 15/44 reads (34%) | catalogued as rs1193637344, COSV66787362; called by muse, mutect2, varscan2
- CRACD | c.1063G>A p.A355T | Missense Mutation (SNP) | VAF 6/19 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.073); catalogued as rs568276295, COSV51715441; called by muse, varscan2
- CSMD3 | c.484A>T p.S162C | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.765); catalogued as COSV52216988; called by muse, mutect2, varscan2
- ESPN | c.439G>A p.A147T | Missense Mutation (SNP) | VAF 27/56 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs727504727; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FLG | c.3403A>G p.R1135G | Missense Mutation (SNP) | VAF 42/99 reads (42%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs372726892, COSV64236302; called by muse, mutect2, varscan2
- GLI3 | c.2740G>A p.G914S | Missense Mutation (SNP) | VAF 69/97 reads (71%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.803); catalogued as rs147004305; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- H4C11 | c.251C>T p.A84V | Missense Mutation (SNP) | VAF 45/97 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.046); catalogued as rs1234191510; called by muse, mutect2, varscan2
- PEG3 | c.412G>A p.V138M | Missense Mutation (SNP) | VAF 62/209 reads (30%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs369229885; called by muse, mutect2, varscan2
- TRH | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 117/390 reads (30%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.904); catalogued as rs769174350; called by muse, mutect2, varscan2
- TSGA10IP | c.1220G>A p.R407Q | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as rs753175238, COSV73245241; called by muse, mutect2, varscan2
- ABCC2 | c.799C>G p.Q267E | Missense Mutation (SNP) | VAF 81/210 reads (39%) | SIFT tolerated (0.61); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARHGAP5 | c.1693G>A p.D565N | Missense Mutation (SNP) | VAF 30/73 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CCNA1 | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 46/97 reads (47%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- CD109 | c.3899A>G p.N1300S | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT tolerated (0.21); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- DNAH14 | c.9347C>T p.A3116V (on ENST00000445597; = p.A4124V on NM_001367479.1) | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT tolerated (0.27); PolyPhen benign (0.087); called by muse, mutect2
- FAM135B | c.2770T>A p.S924T | Missense Mutation (SNP) | VAF 37/87 reads (43%) | SIFT tolerated (0.32); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGLV3-25 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 81/161 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- LRFN5 | c.1739G>A p.G580D | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- MAGI2 | c.250G>T p.A84S | Missense Mutation (SNP) | VAF 72/108 reads (67%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.589); called by muse, mutect2, varscan2
- MCL1 | c.641G>A p.R214Q | Missense Mutation (SNP) | VAF 84/176 reads (48%) | SIFT deleterious (0.02); PolyPhen benign (0.012); called by muse, varscan2
- MDN1 | c.5518T>G p.F1840V | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- MYO5B | c.2368del p.A790Lfs*3 | Frame Shift Del (DEL) | VAF 40/102 reads (39%) | called by mutect2, pindel, varscan2
- NELFA | c.1600C>T p.P534S (on ENST00000542778; = p.P523S on NM_005663.5) | Missense Mutation (SNP) | VAF 7/164 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.168); called by muse, mutect2
- PAN3 | c.103G>T p.G35C | Missense Mutation (SNP) | VAF 45/92 reads (49%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SYNE2 | c.6113T>C p.L2038S | Missense Mutation (SNP) | VAF 89/197 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- TAMM41 | c.1102G>C p.A368P | Missense Mutation (SNP) | VAF 108/302 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZAN | c.5135C>T p.P1712L | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.3); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- AFP | c.1633C>T p.L545= | Silent (SNP) | VAF 15/50 reads (30%) | called by muse, mutect2, varscan2
- ANO2 | c.1041C>A p.L347= (on ENST00000356134 / NM_001278597.3; = p.L351= on NM_001278596.3) | Silent (SNP) | VAF 67/142 reads (47%) | catalogued as COSV59013830; called by muse, mutect2, varscan2
- EDN1 | c.579C>G p.P193= | Silent (SNP) | VAF 121/279 reads (43%) | called by muse, mutect2
- IGLV3-25 | c.189G>A p.V63= | Silent (SNP) | VAF 58/116 reads (50%) | catalogued as rs192338803; called by muse, mutect2, varscan2
- PRR35 | c.1374G>T p.V458= | Silent (SNP) | VAF 51/101 reads (50%) | called by muse, mutect2, varscan2
- PTPA | c.582C>T p.F194= (on ENST00000337738 / NM_178001.2; = p.F159= on NM_021131.5) | Silent (SNP) | VAF 21/63 reads (33%) | catalogued as rs768974475, COSV61235453; called by muse, mutect2, varscan2
- WHAMM | c.180G>A p.R60= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs1298331680; called by muse, mutect2, varscan2
- ZNF837 | c.1131C>T p.H377= | Silent (SNP) | VAF 30/63 reads (48%) | catalogued as COSV69893254; called by muse, mutect2, varscan2
- AC006059.2 | c.*103C>A | 3'UTR (SNP) | VAF 69/106 reads (65%) | catalogued as COSV100045896; called by muse, mutect2, varscan2
- ADAMTSL1 | c.*814G>A | 3'UTR (SNP) | VAF 49/100 reads (49%) | catalogued as rs529794827; called by muse, mutect2, varscan2
- ANKRD53 | c.*16C>G | 3'UTR (SNP) | VAF 44/106 reads (42%) | catalogued as rs1405704033; called by muse, mutect2, varscan2
- ARL13B | c.-44C>T | 5'UTR (SNP) | VAF 20/220 reads (9%) | catalogued as rs1319639238; called by muse, mutect2
- ATP10D | c.1635+403T>C | Intron (SNP) | VAF 21/69 reads (30%) | catalogued as rs909141338; called by muse, mutect2, varscan2
- CERS5 | c.*335C>T | 3'UTR (SNP) | VAF 29/65 reads (45%) | called by muse, mutect2, varscan2
- CHRM3 | c.*1456G>A | 3'UTR (SNP) | VAF 28/67 reads (42%) | catalogued as rs1411026195; called by muse, mutect2, varscan2
- CLEC14A | c.*1G>A | 3'UTR (SNP) | VAF 84/214 reads (39%) | called by muse, mutect2, varscan2
- CMKLR1 | c.*82C>A | 3'UTR (SNP) | VAF 16/54 reads (30%) | called by muse, mutect2, varscan2
- DHFR2 | c.*1873G>T | 3'UTR (SNP) | VAF 127/327 reads (39%) | called by muse, mutect2, varscan2
- DPYD | c.483+1679T>C | Intron (SNP) | VAF 22/38 reads (58%) | called by muse, mutect2, varscan2
- GLIS3 | c.*3336del | 3'UTR (DEL) | VAF 4/37 reads (11%) | catalogued as rs200420290, COSV60930434, COSV60933121; ClinVar: uncertain significance; called by pindel, varscan2*
- HPGD | c.*1115A>C | 3'UTR (SNP) | VAF 65/94 reads (69%) | called by muse, mutect2, varscan2
- IBTK | c.*224T>G | 3'UTR (SNP) | VAF 17/39 reads (44%) | called by muse, mutect2, varscan2
- IL7R | c.*2707T>C | 3'UTR (SNP) | VAF 75/107 reads (70%) | called by muse, mutect2, varscan2
- JAKMIP2 | c.*1014A>C | 3'UTR (SNP) | VAF 42/134 reads (31%) | called by muse, mutect2, varscan2
- KLHL1 | c.*488A>G | 3'UTR (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- LRRIQ3 | c.573+2516G>A | Intron (SNP) | VAF 35/86 reads (41%) | called by muse, mutect2, varscan2
- MAPRE2 | c.*2223A>C | 3'UTR (SNP) | VAF 25/62 reads (40%) | called by muse, mutect2, varscan2
- MME | c.*2435G>A | 3'UTR (SNP) | VAF 19/97 reads (20%) | called by muse, mutect2, varscan2
- NCAM1 | c.2456+1669C>T | Intron (SNP) | VAF 11/29 reads (38%) | called by muse, mutect2, varscan2
- PDPN | c.*1661C>T | 3'UTR (SNP) | VAF 14/24 reads (58%) | catalogued as rs1181860232; called by muse, mutect2, varscan2
- PRR18 | c.*754G>A | 3'UTR (SNP) | VAF 12/63 reads (19%) | catalogued as COSV59454823; called by muse, mutect2, varscan2
- RABGEF1 | chr7:66811346 del T | 3'Flank (DEL) | VAF 29/104 reads (28%) | called by mutect2, pindel, varscan2
- RNF146 | c.*56G>C | 3'UTR (SNP) | VAF 62/134 reads (46%) | called by muse, mutect2, varscan2
- S1PR3 | c.-147-2010G>T | Intron (SNP) | VAF 57/178 reads (32%) | called by muse, mutect2, varscan2
- SH3PXD2A | c.*2259del | 3'UTR (DEL) | VAF 14/34 reads (41%) | catalogued as rs1025839110; called by mutect2, varscan2
- SLC11A2 | chr12:50979522 del GTTTCATCTAGA | 3'Flank (DEL) | VAF 5/12 reads (42%) | called by mutect2, varscan2
- SLC22A11 | c.*988G>A | 3'UTR (SNP) | VAF 40/118 reads (34%) | catalogued as rs897429912; called by muse, mutect2, varscan2
- SLC22A2 | c.1065-523G>C | Intron (SNP) | VAF 20/31 reads (65%) | called by muse, mutect2, varscan2
- SLC26A4 | c.164+21C>T | Intron (SNP) | VAF 7/25 reads (28%) | called by muse, mutect2, varscan2
- SON | c.6321+254A>G | Intron (SNP) | VAF 62/119 reads (52%) | called by muse, mutect2, varscan2
- SPANXN2 | c.-582T>A | 5'UTR (SNP) | VAF 92/96 reads (96%) | called by muse, mutect2
- SPP1 | c.*227G>A | 3'UTR (SNP) | VAF 17/45 reads (38%) | called by muse, mutect2, varscan2
- TMED5 | c.*2269T>C | 3'UTR (SNP) | VAF 12/46 reads (26%) | catalogued as rs1416029308; called by muse, mutect2, varscan2
- TRIM71 | c.*137A>T | 3'UTR (SNP) | VAF 5/55 reads (9%) | catalogued as rs1239818666, COSV67470745; called by muse, mutect2
- TXNIP | c.*1408A>G | 3'UTR (SNP) | VAF 10/22 reads (45%) | called by muse, varscan2
- UPK2 | c.*84C>T | 3'UTR (SNP) | VAF 21/66 reads (32%) | called by muse, mutect2, varscan2
- ZNF398 | c.*1571T>C | 3'UTR (SNP) | VAF 34/64 reads (53%) | called by muse, mutect2, varscan2
- ZNF726 | c.226+249G>C | Intron (SNP) | VAF 25/125 reads (20%) | called by muse, mutect2, varscan2
